Somatic mutation profile of tumor specimen TCGA-27-2521-01A (aliquot TCGA-27-2521-01A-01D-1494-08) from TCGA case TCGA-27-2521, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 34.7 years (12,685 days).
Specimen TCGA-27-2521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54c8d67b-b00e-4b7e-bdfd-2df730970784.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2521-10A (Blood Derived Normal), aliquot TCGA-27-2521-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/097a9469-48c7-477a-a769-cda7ff93271e

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 55/166 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACADVL | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140629318, CM024582, CM990086, COSV50039777; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- APOA5 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 118/199 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57065142; called by muse, mutect2, varscan2
- ATP6V1C2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598832, COSV55365148; called by muse, mutect2
- ATRX | c.5219C>G p.S1740* | Nonsense Mutation (SNP) | VAF 62/72 reads (86%) | catalogued as COSV64871214, COSV64883603; called by muse, mutect2, varscan2
- BRCA2 | c.5897A>G p.H1966R | Missense Mutation (SNP) | VAF 126/263 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs80358823, COSV66462449; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- CLSTN2 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs200855654, COSV71725274; called by muse, mutect2, varscan2
- CRLF2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.363); catalogued as rs374874204, COSV67494236; called by muse, mutect2, varscan2
- CSF2 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51522886; called by muse, mutect2
- FAAH | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as COSV54546002; called by muse, mutect2
- FBXO22 | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs370353595, COSV57618982; called by muse, mutect2, varscan2
- FLG2 | c.2492C>A p.S831Y | Missense Mutation (SNP) | VAF 19/648 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs867314560, COSV66166576; called by muse, mutect2
- GDF6 | c.408C>G p.D136E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV54627682; called by muse, mutect2, varscan2
- GLT6D1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.018); catalogued as rs756944725, COSV65628537; called by mutect2, varscan2
- GNGT2 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV55930341; called by muse, mutect2, varscan2
- GOLGA3 | c.1562A>T p.D521V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs937056192, COSV52643920; called by muse, mutect2
- GPR4 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59918328; called by muse, mutect2
- GRIP1 | c.2382G>A p.M794I (on ENST00000359742 / NM_001379345.1; = p.M742I on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1300773016, COSV54043288; called by muse, mutect2
- HIVEP2 | c.2609A>G p.Q870R | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV50064910; called by muse, mutect2, varscan2
- HOOK1 | c.893A>T p.E298V | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64620971; called by muse, mutect2, varscan2
- IFNW1 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV66522492; called by muse, varscan2
- IGHV3-21 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 140/381 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as rs781842811; called by muse, varscan2
- ITGB8 | c.643A>G p.N215D | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as COSV56006364, COSV56014442; called by muse, mutect2, varscan2
- LAMA2 | c.4381G>T p.G1461* | Nonsense Mutation (SNP) | VAF 24/235 reads (10%) | catalogued as COSV70342112, COSV70355214; called by muse, mutect2, varscan2
- MACF1 | c.1772A>T p.E591V | Missense Mutation (SNP) | VAF 59/332 reads (18%) | catalogued as COSV58402859; called by muse, mutect2, varscan2
- MPP7 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 145/379 reads (38%) | catalogued as rs755262754, COSV61738191; called by muse, mutect2, varscan2
- MYO18A | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV62873468; called by muse, mutect2, varscan2
- OR2Z1 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 125/223 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV60693353; called by muse, mutect2, varscan2
- ORC5 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV52402877; called by muse, mutect2, varscan2
- PDE4B | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58496211; called by muse, mutect2, varscan2
- POTED | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs374506316; called by muse, mutect2
- RIOX2 | c.1316A>G p.K439R (on ENST00000333396 / NM_001042533.2; = p.K438R on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV51716222; called by muse, mutect2, varscan2
- RRAD | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100234040, COSV55337669; called by muse, mutect2, varscan2
- SCLY | c.998A>T p.D333V (on ENST00000651534; = p.D325V on NM_016510.7) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV54544425; called by muse, mutect2, varscan2
- SLC13A2 | c.1550T>C p.V517A | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58998866; called by muse, mutect2
- SLC44A3 | c.1096G>A p.G366S (on ENST00000271227 / NM_001114106.3; = p.G318S on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs750325501, COSV54731766, COSV54733566; called by muse, mutect2, varscan2
- SLC7A14 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51590271; called by muse, mutect2
- SLITRK6 | c.362A>C p.H121P | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV68391724; called by muse, mutect2
- STAB1 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771649805, COSV58742683; called by muse, mutect2, varscan2
- STAR | c.180T>C p.G60= | Splice Region (SNP) | VAF 20/52 reads (38%) | catalogued as COSV52418494; called by muse, mutect2, varscan2
- TP53 | c.789del p.L264Yfs*81 | Frame Shift Del (DEL) | VAF 41/60 reads (68%) | catalogued as COSV52935703, COSV53210322; called by mutect2, pindel, varscan2
- TSC2 | c.5251C>T p.R1751C | Missense Mutation (SNP) | VAF 73/104 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781630603, COSV51925769; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WIPI1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 155/335 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs1410429795, COSV50931834; called by muse, mutect2, varscan2
- ZNF71 | c.71dup p.P25Tfs*53 | Frame Shift Ins (INS) | VAF 43/66 reads (65%) | catalogued as rs768627914; called by mutect2, pindel, varscan2
- ZNF831 | c.4615G>A p.A1539T | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV64045362; called by muse, mutect2
- CIC | c.2872del p.Q958Sfs*9 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- SUZ12 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ASTN2 | c.3555C>A p.T1185= (on ENST00000313400 / NM_001365069.1; = p.T1134= on NM_014010.5) | Silent (SNP) | VAF 95/149 reads (64%) | catalogued as COSV56015163; called by muse, mutect2, varscan2
- GORAB | c.282C>T p.P94= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as rs767686838, COSV63026930; called by muse, mutect2, varscan2
- GRM4 | c.1902C>T p.F634= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV65219834; called by muse, mutect2, varscan2
- IFNW1 | c.462G>C p.L154= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV66521772, COSV66522499; called by muse, varscan2
- LRRIQ4 | c.1638A>G p.G546= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52983060; called by muse, mutect2, varscan2
- MAGEB16 | c.486A>G p.L162= | Silent (SNP) | VAF 88/94 reads (94%) | catalogued as rs1184974019, COSV101303264, COSV67874614; called by muse, mutect2, varscan2
- MAPK8IP1 | c.585A>T p.S195= | Silent (SNP) | VAF 18/213 reads (8%) | catalogued as COSV53799906; called by muse, mutect2
- MDC1 | c.1218C>T p.D406= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as rs764506177, COSV64527693; called by muse, mutect2
- PRAMEF2 | c.93G>A p.L31= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV53576865, COSV53579341; called by muse, mutect2, varscan2
- SLC39A3 | c.597C>T p.S199= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV54119071; called by muse, mutect2, varscan2
- SOX30 | c.1464C>T p.S488= | Silent (SNP) | VAF 56/75 reads (75%) | catalogued as rs753364331, COSV53939690; called by muse, mutect2, varscan2
- SPTLC3 | c.399C>G p.A133= | Silent (SNP) | VAF 152/453 reads (34%) | catalogued as COSV65468804; called by muse, mutect2
- TET3 | c.4482C>T p.P1494= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs764597295, COSV69642000; called by muse, mutect2, varscan2
- WDR13 | c.582C>T p.D194= | Silent (SNP) | VAF 45/52 reads (87%) | catalogued as rs782080281, COSV54331717, COSV54333657; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF618 | c.2400G>T p.P800= (on ENST00000374126 / NM_001318042.2; = p.P707= on NM_133374.2) | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV55929906; called by muse, mutect2
- DELEC1 | n.586C>G | RNA (SNP) | VAF 11/113 reads (10%) | catalogued as COSV64986694; called by muse, mutect2, varscan2
- HNRNPU | c.634+1207G>C | Intron (SNP) | VAF 18/264 reads (7%) | catalogued as COSV51694377; called by muse, mutect2
